TCGA case TCGA-CQ-A4CD — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites; Tissue source site: University Health Network, Toronto. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/15eb8d88-adb1-4f4f-a44d-087049db60ce

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C41.1; Tissue or organ of origin: Mandible; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 69.8 years (25,497 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: T4b; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IVB; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 0; Lymph nodes tested: 47; Lymphatic invasion present: No; Margin status: Indeterminate; Perineural invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 156 days; Days to treatment end: 204 days; Treatment dose: 6,600 cGy; Treatment outcome: Complete Response; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Cure; Days to treatment end: 204 days; Treatment outcome: No Measurable Disease.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 548 days (1.5 years); Disease response: Tumor Free.
- Days to follow up: 998 days (2.7 years); Disease response: Tumor Free.
- Days to follow up: 1,022 days (2.8 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.
- Alcohol history: No; Alcohol drinks per day: 0; Alcohol days per week: 0.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CQ-A4CD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 100 mg.
  Slide TCGA-CQ-A4CD-01A-02-TS2: Section location: Top; Percent tumor cells: 33; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 17; Percent stromal cells: 50; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-CQ-A4CD-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CQ-A4CD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Anatomic organ subdivision: Oral Cavity; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Close; Lymphovascular invasion: No; Tobacco smoking history indicator: 1; Alcohol history documented: Yes; Alcohol consumption frequency: 0; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Radiation; Definitive treatment evidence disease after: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,022 days; disease-specific survival: no event (censored), 1,022 days; progression-free interval: no event (censored), 1,022 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CQ-A4CD-01A-21D-A253-01): tumor purity 0.52, ploidy 2.06, whole-genome doublings 0.
